TARGET case TARGET-50-PALAXJ — High-Risk Wilms Tumor (TARGET-WT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Complex Mixed and Stromal Neoplasms; Primary site: Kidney. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/5d617dc5-3a26-5d5b-9ed6-ecac7d198d26

Demographics
Sex at birth: female; Race: other; Age at index: 4 years; Vital status: Alive.

Diagnoses (1)
1. Wilms tumor: ICD-O-3 morphology code: 8960/3; ICD-10 code: C64; Tissue or organ of origin: Kidney, NOS; Classification of tumor: primary; Age at diagnosis: 4.1 years (1,514 days); Year of diagnosis: 2001; Days to last follow up: 2,042 days (5.6 years); Pediatric kidney staging: Nephrectomy specimen with tumor that is present at the surgical margin of resection or within regional lymph nodes, no distant metastasis; Wilms tumor histologic subtype: Unfavorable.
   Treatment given: Protocol identifier: NWTS-5.

Follow-up (1 entry)
- Days to follow up: 2,042 days (5.6 years); Event-free: no event (relapse, second malignancy or death) recorded through day 2,042; Year of follow up: 2011.

Biospecimens (1 sample)
- Sample TARGET-50-PALAXJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.

Additional fields from the TARGET clinical supplement workbook TARGET_WT_ClinicalData_Discovery_and_Validation_Percent_Tumor_Nuclei_and_Necrosis_Supplement_20230322.xlsx (sheet WT Data), for sample TARGET-50-PALAXJ-01A:
- Histological Subtype: anaplastic Wilms
- Specimen Type: frozen solid tumor
- Pathology: Diagnosis Confirmed: Yes
- % Tumor Nuclei: Top: 50
- % Non tumor Nuclei: Top: 50
- % Cellular Tumor: Top: 5
- % Normal: Top: 0
- % Stroma: Top: 10
- % Necrosis: Top: 85
- % Tumor Nuclei: Bottom: 25
- % Non tumor Nuclei: Bottom: 75
- % Cellular Tumor: Bottom: 3
- % Normal: Bottom: 0
- % Stroma: Bottom: 7
- % Necrosis: Bottom: 90
- Pathology Pass/Fail: Fail

Additional fields from the TARGET clinical supplement workbook TARGET_WT_ClinicalData_Discovery_and_Validation_Percent_Tumor_Nuclei_and_Necrosis_Supplement_20230322.xlsx (sheet WT Data), for sample TARGET-50-PALAXJ-01A-02:
- Histological Subtype: anaplastic Wilms
- Specimen Type: frozen solid tumor
- Pathology: Diagnosis Confirmed: yes
- % Tumor Nuclei: Top: 60
- % Non tumor Nuclei: Top: 40
- % Cellular Tumor: Top: 25
- % Normal: Top: 0
- % Stroma: Top: 25
- % Necrosis: Top: 50
- % Tumor Nuclei: Bottom: 70
- % Non tumor Nuclei: Bottom: 30
- % Cellular Tumor: Bottom: 40
- % Normal: Bottom: 0
- % Stroma: Bottom: 10
- % Necrosis: Bottom: 50
- Pathology Pass/Fail: fail

Additional fields from the TARGET clinical supplement workbook TARGET_WT_ClinicalData_Validation_20230322.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 2042
- Stage: III
- ICD-O-3-T: C649
- Histologic Classification of Primary Tumor: DAWT
